Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4173, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4173-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

[REDACTED] with large 9 x 9 cm right renal mass.

Specimens Submitted:

- 1: SP: Right kidney [REDACTED]
2: SP: Paracaval nodes [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, RIGHT; RADICAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 9.5 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY SHOWS FOCAL CHRONIC PYELONEPHRITIS AND GLOMERULOSCLEROSIS.
- THE ADRENAL GLAND IS NOT SUBMITTED.
- 2) LYMPH NODES, PARACAVAL; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- [REDACTED]
- [REDACTED]
-
- [REDACTED]

1) The specimen is received fresh, labeled "Right Kidney". It consists of a total nephrectomy specimen weighing 892 grams and measuring 15.5 x 10.2 x 6.4 cm in overall dimensions. No adrenal gland identified. The tumor measures 9.5 x 7.2 x 5.9 cm and is located at the lower pole of the kidney, extending to the middle portion. The tumor is lobulated with a brown-yellow parenchyma and multiple areas of hemorrhage and necrosis. The renal pelvis is not directly involved by tumor. The non-neoplastic kidney has a normal architecture. The surface of the specimen is inked and a portion of the specimen is submitted for TPS. Photographs are taken before and after the bisection. Representative sections are submitted.

Summary of Sections:

FSC - frozen section control

T - tumor

NL - normal kidney

RPV - renal pelvis

TPCE - tumor with possible pericortical extension

MS - margin sections

[REDACTED]

[page 2 of 2]
2). The specimen is received in formalin labeled, "Paracaval nodes". It consists of multiple pieces of yellow tan fatty tissue measuring 4.0 x 3.0 x 0.8 cm in aggregate. On dissection, there are multiple lymph nodes identified measuring 1.2 X 1.2 X. 0.4 cm in aggregate. The lymph nodes are entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: SP: Right kidney (fs) (tl/lmg)

Block	Sect. Site	PCs
1	fsc	1
1	ms	1
1	nl	1
1	rpv	1
6	t	6
2	tpce	2

Part 2: SP: Paracaval nodes (tl)

Block	Sect. Site	PCs
1	u	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: CORTICAL NEOPLASM, FAVORING RENAL CELL CARCINOMA, CONVENTIONAL CLEAR CELL TYPE. [REDACTED]
PERMANENT DIAGNOSIS: SAME.
-

Source: NCI Genomic Data Commons file 3193b944-017b-4161-9ac6-665616fb028e (TCGA-BP-4173.FCBE8ED4-84F1-4A59-A958-95795DEC0C29.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).